Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-5677, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-5677-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

DIAGNOSIS

(A) RIGHT KIDNEY AND ADRENAL, RADICAL NEPHRECTOMY:

KIDNEY:

RENAL CELL CARCINOMA, CLEAR CELL TYPE, FUHRMAN GRADE IV/IV.

TUMOR SIZE: 6.5 X 6.5 X 2.3 CM.

TUMOR INVADES INTO PERINEPHRIC FATTY TISSUE AND APPROACHES TO WITHIN <0.1 MM OF THE INKED SOFT TISSUE RESECTION MARGIN.

TUMOR INVADES RENAL SINUS FAT.

VASCULAR/LYMPHATIC INVASION BY TUMOR IS PRESENT.

Renal artery segment, unremarkable.

Renal vein resection margin, free of tumor.

Ureter segment, unremarkable.

Adrenal gland, no tumor present.

(B) GALLBLADDER, CHOLECYSTECTOMY:

Cholelithiasis.

Mild chronic cholecystitis.

GROSS DESCRIPTION

(A) RIGHT KIDNEY - A nephrectomy specimen (18.0 x 7.0 x 4.0 cm) includes: the tumor-distorted right kidney (14.0 x 6.0 x 2.2 cm), segment of unremarkable renal artery, renal vein segment, unremarkable ureter segment (9.0 cm in length and 0.5 cm in average diameter), and unremarkable adrenal gland (5.0 x 1.8 x 0.4 cm).

There is a 6.5 x 6.5 x 2.3 cm well circumscribed tumor in the upper pole of the kidney. The tumor is predominantly yellow with pink areas and about 60-70% random areas of necrosis. The tumor appears to invade the perinephric adipose tissue but do not extend to the Gerota's fascia. The adjacent kidney parenchyma is unremarkable..

INK CODE:

Black: Gerota's fascia.

SECTION CODE:

A01, ureter, renal vein and renal artery margin;

A02-A05, mass with Gerota's fascia (inked black);

A06-A08, mass with adrenal gland;

A09,A10, mass with normal portion of the kidney;

A11-A14, mass;

A15, A16, normal kidney, representative sections. [REDACTED]

[NOTE: Portions of the tumor have been submitted for electron microscopy (from formalin in glutaraldehyde) and research protocols.]

(B) GALLBLADDER - An intact gallbladder measuring 11.0 cm in length and 6.5 cm in maximum circumference. The bile is dark green. The mucosa is pink-green. The wall of the gallbladder is 0.2 cm in thickness. Multiple irregular small yellow-green gallstones measuring 1.0 x 1.0 x 0.3 cm, the largest one.

SECTION CODE:

B1, cyst duct;

B2, representative sections of the gallbladder. [REDACTED]

CLINICAL HISTORY

Right renal mass.

Source: NCI Genomic Data Commons file 401441ff-be9b-4e95-bb9b-6143daa07af8 (TCGA-CJ-5677.9725BEEC-CEE9-47F3-8F29-8A5E22F51AA8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).